Gene-level copy-number profile of specimen HCM-CSHL-0240-C18-85A from HCMI case HCM-CSHL-0240-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Medullary carcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 81.9 years (29,899 days).
Specimen HCM-CSHL-0240-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 432c3ec8-07ee-407b-b973-ebaa4efd2d85.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0240-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/8870f099-66fe-447c-8943-425b0bfaceec

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 821; copy number 2: 53,604; copy number 3: 3,970.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,838,903–90,839,037, 1 gene (within-gene range 0–2): TMSB4XP8.
- chr8:98,782,055–98,906,517, 3 genes (within-gene range 0–2): RPL19P14, AC016877.2, MRPL57P7.
- chr8:98,943,595–98,952,104, 2 genes: AC016877.3, OSR2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 703. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
